Gene-level copy-number profile of tumor specimen TCGA-LA-A7SW-01A from TCGA case TCGA-LA-A7SW, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.5 years (26,116 days).
Specimen TCGA-LA-A7SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ba060bae-7479-4dfa-b42d-91e55aca97a4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LA-A7SW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc9fdac9-3628-49ee-bb1c-b41c6ab75fbc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 5,654; copy number 2: 32,026; copy number 3: 11,751; copy number 4: 6,253; copy number 5: 2,555; copy number 6: 805; copy number 7: 277; copy number 8: 86; copy number 9: 25; copy number 10: 85; copy number 11: 55; copy number 12: 69; copy number 13: 14; copy number 14: 21; copy number 16: 21; copy number 18: 59; copy number 19: 28; copy number 21: 3; copy number 24: 12; copy number 31: 2; copy number 48: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LA-A7SW-01A-11D-A400-01): tumor purity 0.48, ploidy 2.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:21,582,096–21,656,869, 2 genes (within-gene range 0–1): AC096576.3, AC096576.1.
- chr10:32,231,849–32,378,798, 4 genes (within-gene range 0–1): RPS24P13, AL158834.2, EPC1, AL158834.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,121 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,274,552–81,252,096, 118 genes, copy number 5–11 (broad region; genes not listed).
- chr1:150,780,272–151,699,091, 52 genes, copy number 6 (within-gene range 4–6): AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P.
- chr1:155,749,662–156,572,604, 42 genes, copy number 5 (within-gene range 4–5): GON4L, AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1, IQGAP3.
- chr1:206,747,980–210,171,389, 73 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:219,962,652–220,784,815, 27 genes, copy number 5: U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2.
- chr1:225,964,179–226,446,292, 17 genes, copy number 8: NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703, AL512343.1, ACBD3, ACBD3-AS1, AL592045.1, MIXL1, LIN9, YBX1P9, AL359742.1, PARP1, AL359704.1, RPS3AP7, RN7SKP165.
- chr3:183,919,934–184,508,399, 35 genes, copy number 5 (within-gene range 4–5): ABCC5, ABCC5-AS1, EEF1A1P8, HTR3D, HTR3C, HTR3C2P, Y_RNA, HTR3E-AS1, HTR3E, HSP90AA5P, AC131235.3, AC131235.2, EIF2B5, AC131235.1, DVL3, AP2M1, ABCF3, VWA5B2, MIR1224, ALG3, EEF1AKMT4, EEF1AKMT4-ECE2, CAMK2N2, ECE2, PSMD2, EIF4G1, SNORD66, FAM131A, CLCN2, POLR2H, THPO, CHRD, LINC02054, AC128714.2, LINC01839.
- chr3:186,717,348–189,897,276, 53 genes, copy number 5–11: KNG1, PSMD10P2, RNU6-1105P, GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944.
- chr7:192,571–16,645,817, 268 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr7:44,748,581–57,203,597, 248 genes, copy number 6–8 (broad region; genes not listed).
- chr7:66,682,164–67,239,519, 16 genes, copy number 5 (within-gene range 3–5): RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1.
- chr8:58,411,359–59,119,147, 9 genes, copy number 7 (within-gene range 4–7): UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P.
- chr8:110,334,743–137,425,021, 314 genes, copy number 5–6 (broad region; genes not listed).
- chr9:27,948,078–28,888,955, 6 genes, copy number 6 (within-gene range 4–6): LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873.
- chr10:5,510,036–5,566,881, 5 genes, copy number 7 (within-gene range 4–7): CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2.
- chr10:56,357,227–64,693,446, 77 genes, copy number 6–48 (within-gene range 3–48) (broad region; genes not listed).
- chr11:65,213,840–66,364,804, 89 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:109,982,192–110,464,884, 6 genes, copy number 5: RPSAP50, AP001981.1, AP001889.1, ZC3H12C, LINC02732, FDX1.
- chr12:6,155,035–17,711,046, 417 genes, copy number 5–7 (broad region; genes not listed).
- chr12:19,089,151–34,249,958, 284 genes, copy number 5 (broad region; genes not listed).
- chr13:72,703,693–77,422,847, 64 genes, copy number 10–19 (broad region; genes not listed).
- chr13:85,046,001–92,873,682, 70 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr13:94,757,451–97,902,288, 41 genes, copy number 5–12: BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24, HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, AL359502.2, RPL7AP61.
- chr13:108,335,354–112,052,138, 55 genes, copy number 5–9 (within-gene range 4–9): AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1, TEX29, AL359649.1, LINC02337, LINC00354, AL138691.1.
- chr13:112,313,467–114,337,626, 63 genes, copy number 6 (broad region; genes not listed).
- chr14:18,333,726–21,090,248, 166 genes, copy number 6 (broad region; genes not listed).
- chr14:21,749,178–22,190,713, 44 genes, copy number 7: TRAV5, RPL4P1, TRAV6, TRAV7, TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:22,202,583–22,227,254, 4 genes, copy number 7: TRAV26-2, TRAV34, TRAV35, TRAV36DV7.
- chr14:43,990,539–44,567,467, 8 genes, copy number 8: LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1.
- chr14:50,418,501–54,902,826, 96 genes, copy number 7–10 (within-gene range 2–10) (broad region; genes not listed).
- chr14:55,896,443–56,427,032, 6 genes, copy number 11 (within-gene range 2–11): AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284.
- chr15:74,202,705–75,455,842, 67 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:90,074,512–90,314,499, 20 genes, copy number 7: ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P.
- chr16:66,408,524–67,385,204, 60 genes, copy number 5: LINC00920, BEAN1, AC132186.1, BEAN1-AS1, AC010542.3, TK2, AC010542.2, AC010542.4, Y_RNA, CKLF, CKLF-CMTM1, AC010542.5, CMTM1, CMTM2, AC010542.1, CMTM3, CMTM4, DYNC1LI2, AC018557.1, AC018557.3, AC018557.2, AC044802.1, TERB1, NAE1, AC044802.2, CA7, PDP2, CDH16, RRAD, CIAO2B, CES2, AC009084.1, AC009084.3, CES3, CES4A, AC009084.2, RN7SL543P, CBFB, C16orf70, B3GNT9, TRADD, FBXL8, AC074143.1, HSF4, NOL3, KIAA0895L, EXOC3L1, E2F4, ELMO3, MIR328, AC040160.2, LRRC29, TMEM208, FHOD1, SLC9A5, AC040160.1, PLEKHG4, KCTD19, RN7SKP118, LRRC36.
- chr17:27,082,690–27,991,787, 34 genes, copy number 5–12: TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3.
- chr19:27,638,483–41,881,372, 567 genes, copy number 5–21 (broad region; genes not listed).
- chr19:50,621,307–55,259,017, 392 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–4,195,953, 139 genes, copy number 5 (broad region; genes not listed).
- chr20:62,544,343–63,085,071, 33 genes, copy number 6: MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056.
- chr21:33,057,829–33,931,607, 24 genes, copy number 5 (within-gene range 3–5): LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2, TMEM50B, RPS5P3, AP000302.1, DNAJC28, GART, BTF3P6, SON, MIR6501, DONSON, AP000311.1, CRYZL1, ITSN1.

Autosomal genes at a single copy (total copy number 1): 5,644. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
